FM case AD13092 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/987f3798-957c-479b-8397-940bf4640bee

Female, 65.4 years: Follicular carcinoma, NOS (ICD-O-3 8330/3) of the thyroid gland; metastasis biopsied or resected from the thyroid gland. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
